Gene-level copy-number profile of tumor specimen ALCH-B2TN-TTP1-C from ALCHEMIST case ALCH-B2TN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.0 years (22,280 days).
Specimen ALCH-B2TN-TTP1-C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 39f9cf6c-dfd8-4dcc-b600-a3e72fe19d58.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2TN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/4bd7acb7-7966-434a-b3f7-5986ee192fd3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 5,174; copy number 2: 48,375; copy number 3: 5,117; copy number 4: 173; copy number 5: 37; copy number 6: 1; copy number 7: 2; copy number 8: 2; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:227,554–229,557, 1 gene (within-gene range 0–3): AC145676.1.
- chr8:140,572,142–140,572,812, 1 gene (within-gene range 0–2): AC067931.1.
- chr8:144,466,043–144,502,121, 3 genes (within-gene range 0–1): KIFC2, FOXH1, PPP1R16A.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr10:86,654,547–86,736,072, 2 genes: OPN4, LDB3.
- chr11:1,991,096–2,001,470, 5 genes: LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr14:104,579,764–104,590,515, 2 genes (within-gene range 0–3): C14orf180, BX927359.1.
- chr16:2,090,195–2,090,284, 1 gene (within-gene range 0–1): MIR1225.
- chr17:14,295,512–14,297,600, 1 gene: AC005224.1.
- chr17:14,303,854–14,305,505, 1 gene (within-gene range 0–2): AC005224.3.
- chr19:13,836,287–13,836,659, 3 genes: MIR24-2, MIR27A, MIR23A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 43 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:63,291,518–63,359,306, 8 genes, copy number 5: ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4.
- chr11:1,947,278–1,989,920, 2 genes, copy number 6–10: MRPL23, MRPL23-AS1.
- chr19:20,122,569–20,321,305, 1 gene, copy number 5 (within-gene range 1–5): AC011447.3.
- chr19:20,167,214–20,331,517, 12 genes, copy number 5: ZNF486, BNIP3P16, AC011447.4, AC011447.6, AC011447.7, BNIP3P17, AC078899.3, AC078899.1, BNIP3P18, AC078899.4, BNIP3P19, AC078899.5.
- chr19:29,811,991–30,957,192, 16 genes, copy number 5: CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1.
- chr21:43,414,483–43,479,534, 4 genes, copy number 7–8: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 2,331. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
